Gene-level copy-number profile of tumor specimen ALCH-B29Y-TTP1-A from ALCHEMIST case ALCH-B29Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,037 days).
Specimen ALCH-B29Y-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 151f8334-ec71-46ae-8e36-e1c11f810079.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B29Y-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/97bba9f1-54f4-4165-a5f2-ca6fec2b79f9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 208; copy number 2: 20,988; copy number 3: 3,104; copy number 4: 29,703; copy number 5: 1,754; copy number 6: 2,414; copy number 7: 66; copy number 10: 73; copy number 12: 2; copy number 25: 1; copy number 49: 2.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:239,943,015–239,943,094, 1 gene (within-gene range 0–2): MIR4786.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:99,392,048–99,534,700, 10 genes (within-gene range 0–2): PDAP1, BUD31, PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF, ZNF789, ZNF394, ZKSCAN5.
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–2): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr9:63,974,762–66,745,929, 53 genes: AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P, CDRT15P12, RBPJP2, RAB28P4, ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr22:21,370,064–21,371,945, 1 gene: AP000552.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 78 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,459,455–130,509,707, 2 genes, copy number 12: POTEI, RNU6-473P.
- chr22:19,330,698–20,704,606, 73 genes, copy number 10 (broad region; genes not listed).
- chr22:21,141,624–21,142,371, 1 gene, copy number 25: E2F6P2.
- chr22:21,300,990–21,325,042, 2 genes, copy number 49 (within-gene range 5–49): FAM230H, AP000552.2.

Autosomal genes at a single copy (total copy number 1): 207. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
